Gene-level copy-number profile of tumor specimen C3L-06766-01 from CPTAC case C3L-06766, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.0 years (18,266 days).
Specimen C3L-06766-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Fundus Of Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8fad0839-6d2e-4855-9f49-cbec3488cc12.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06766-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/1b3aa114-b78c-4498-8dfb-5dca7f317da6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 107; copy number 1: 2,280; copy number 2: 54,986; copy number 3: 1,470; copy number 4: 63.

Homozygous deletions (total copy number 0; autosomes only): 102 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,052,514–22,552,156, 97 genes (within-gene range 0–2) (broad region; genes not listed).
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–3): RPS10P2.
- chr20:14,933,843–15,280,873, 4 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,768. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
